Somatic mutation profile of tumor specimen BA2589D (aliquot aq-BA2589D) from BEATAML1.0 case 2064, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.5 years (15,508 days).
Specimen BA2589D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0656810-6c1e-4721-b517-1716698beff9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2689D (Solid Tissue Normal), aliquot aq-BA2689D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a071fd8-a9d2-4218-8416-62f1ebc8de75

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Frame Shift Del 1, 5'Flank 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 34/92 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- RIT2 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 3/55 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56303008; called by muse, mutect2
- ADGRB1 | c.4157C>A p.A1386D | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.01); called by muse, mutect2
- ANKRD34A | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- DNMT3A | c.1488del p.C497Vfs*154 | Frame Shift Del (DEL) | VAF 46/116 reads (40%) | called by mutect2, pindel, varscan2
- FAM20B | c.1180G>T p.G394W | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- MYO18B | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- NRROS | c.849C>A p.N283K | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- PUS10 | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2
- SCN9A | c.2953G>T p.A985S (on ENST00000303354; = p.A974S on NM_002977.3) | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- TRPV6 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2
- NLGN3 | c.2052G>A p.Q684= (on ENST00000358741 / NM_181303.2; = p.Q664= on NM_018977.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- FMN1 | c.3929-6766G>T | Intron (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- SP5 | chr2:170714291 C>A | 5'Flank (SNP) | VAF 5/36 reads (14%) | catalogued as rs1366654477; called by muse, mutect2, varscan2
